Somatic mutation profile of tumor specimen 0DI5FJ from CCDI case PBBULG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.4 years (4,157 days).
Specimen 0DI5FJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31059de4-a9e0-4418-9c40-4dab9482d83d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5ED (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc11a432-38a5-4fa1-a26a-7c52af5b6deb

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/694 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 188/1303 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1728_1730del p.R577del (on ENST00000521381 / NM_181523.3; = p.R307del on NM_181504.4) | In Frame Del (DEL) | VAF 194/1370 reads (14%) | hotspot (GDC flag); catalogued as COSV57133583; called by mutect2, varscan2
- AC134980.2 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 182/806 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs1566838399; called by muse, mutect2, varscan2
- TTN | c.80386G>A p.G26796S (on ENST00000591111; = p.G19372S on NM_003319.4) | Missense Mutation (SNP) | VAF 196/1423 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs757770952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 207/1294 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs760177550, COSV56351624; called by muse, mutect2, varscan2
- KRT18 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 160/1070 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- INHBC | c.636G>A p.L212= | Silent (SNP) | VAF 40/608 reads (7%) | called by muse, mutect2
- KRTAP19-5 | c.45C>T p.Y15= | Silent (SNP) | VAF 66/1441 reads (5%) | catalogued as rs759270701, COSV100478566; called by muse, mutect2
